Gene-level copy-number profile of tumor specimen C3N-03458-01 from CPTAC case C3N-03458, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 70.2 years (25,648 days).
Specimen C3N-03458-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b4caba00-203a-41da-a78f-ccd7b46448ef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03458-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/c17b62a4-ace7-44fe-b660-aeb8365ced5b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 194; copy number 1: 1,345; copy number 2: 7,575; copy number 3: 8,140; copy number 4: 35,838; copy number 5: 2,574; copy number 6: 2,517; copy number 7: 349; copy number 8: 181; copy number 9: 172; copy number 16: 31.

Homozygous deletions (total copy number 0; autosomes only): 165 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–2): AC114786.3.
- chr9:4,984,390–5,437,925, 23 genes (within-gene range 0–2): JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1.
- chr9:19,409,009–30,990,572, 141 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 203 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:173,871,653–175,463,180, 39 genes, copy number 9: RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24, OLA1, AC013467.1, RN7SL65P, Y_RNA, LRRC2P1, HNRNPA1P39, LINC01305, AC018470.1, SP9, CIR1, SCRN3, GPR155, AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1.
- chr10:72,053,294–78,675,109, 164 genes, copy number 9–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
